Surgical pathology report (de-identified scan), TCGA case TCGA-RR-A6KC, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital AZ, specimen TCGA-RR-A6KC-01A (Primary Tumor).

Pathology Report

Date of Surgery:

ICD-O-3

Diagnosis:

Left temporal mass
-glioblastoma

Glioblastoma multiforme 9440/3

Glioblastoma NOS 9440/3

Site: Brain Temporal lobe 71.2
QW 6/28/13

Discussion:

Specimen shows typical features of glioblastoma including marked hypercellularity and atypia with both microvascular proliferation and necrosis. Scattered mitotic figures are seen.

Microscopic Description:

Sections demonstrate a markedly hypercellular glial neoplasm that diffusely infiltrates the gray and white matter. The tumor cells resemble atypical fibrillary astrocytes. There is multifocal tumor necrosis. Only a few scattered mitotic figures are seen.

Microvascular proliferation is present.

Source: NCI Genomic Data Commons file 552e2eca-e608-4d40-8150-7c8dd430018e (TCGA-RR-A6KC.53E9E4FC-DBC4-41F0-8AA6-BB5493B324CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).